Somatic mutation profile of tumor specimen C3L-00448-01 (aliquot CPT0010160006) from CPTAC case C3L-00448, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.4 years (24,253 days).
Specimen C3L-00448-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a45130c-01cf-45e6-bb89-65e74b9a8786.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00448-31 (Blood Derived Normal), aliquot CPT0019880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e8d38f0-95cb-4511-87db-b27bc74d0107

The open-access MAF lists 95 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Intron 10, Frame Shift Del 5, 3'UTR 4, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, RNA 2, 5'Flank 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.1690A>T p.I564F | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.284); catalogued as rs780288120; called by muse, mutect2, varscan2
- AMBRA1 | c.2724C>G p.I908M (on ENST00000458649 / NM_001367468.1; = p.I818M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as rs778054395; called by muse, mutect2, varscan2
- ATP6V0D1 | c.935T>G p.F312C | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs372633318; called by muse, mutect2, varscan2
- CDH8 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567571962; called by muse, mutect2, varscan2
- CSNK1G1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57308885; called by muse, mutect2, varscan2
- DHDH | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760489280; called by muse, mutect2, varscan2
- EHHADH | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976593025; called by muse, mutect2, varscan2
- GRK5 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.332); catalogued as COSV64865972; called by muse, mutect2, varscan2
- IRS2 | c.3143C>T p.S1048L | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65477353; called by muse, mutect2, varscan2
- KIAA0513 | c.910del p.L304* | Frame Shift Del (DEL) | VAF 55/219 reads (25%) | catalogued as COSV50741541; called by mutect2, pindel, varscan2
- KRTAP15-1 | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as rs767222787, COSV100481653; called by muse, mutect2, varscan2
- PRKAG3 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1311794331; called by muse, mutect2, varscan2
- PTK2 | c.2965C>G p.L989V | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.783); catalogued as COSV61794731; called by muse, mutect2, varscan2
- SCN10A | c.5556C>A p.D1852E | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV71862113; called by muse, mutect2, varscan2
- TAF13 | c.210C>G p.H70Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs1213655507; called by muse, mutect2, varscan2
- ZNF469 | c.9047C>A p.T3016K (on ENST00000437464; = p.T3044K on NM_001367624.2) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as CM149229, COSV101458852; called by muse, mutect2, varscan2
- ABCD1 | c.1819G>A p.G607S | Missense Mutation (SNP) | VAF 119/188 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ABCG8 | c.1823T>A p.F608Y | Missense Mutation (SNP) | VAF 223/479 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- AGTR2 | c.360del p.F120Lfs*7 | Frame Shift Del (DEL) | VAF 107/204 reads (52%) | called by mutect2, pindel, varscan2
- ANP32A | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ARAP3 | c.2803C>G p.L935V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID1B | c.758A>C p.D253A | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); called by muse, varscan2
- ASL | c.1235A>T p.E412V | Missense Mutation (SNP) | VAF 237/511 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ATP2B1 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BIRC6 | c.11756-15_11756del p.X3919_splice | Splice Site (DEL) | VAF 59/229 reads (26%) | called by mutect2, pindel, varscan2
- BMS1 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BPTF | c.7218_7223dup p.P2407_Q2408dup | In Frame Ins (INS) | VAF 21/132 reads (16%) | called by mutect2, varscan2
- BRMS1L | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.031); called by muse, varscan2
- CANX | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CCDC27 | c.626dup p.L209Ffs*35 | Frame Shift Ins (INS) | VAF 45/153 reads (29%) | called by mutect2, pindel, varscan2
- CDC25C | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL28A1 | c.1650+1G>A p.X550_splice | Splice Site (SNP) | VAF 69/155 reads (45%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GCN1 | c.3449C>G p.S1150* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- GPX1 | c.563T>C p.I188T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- LAMB4 | c.4211G>A p.R1404K | Missense Mutation (SNP) | VAF 142/354 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LATS1 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- LRRC15 | c.1372A>G p.N458D | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MMS22L | c.1204T>G p.L402V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NEK4 | c.2136G>T p.M712I | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, varscan2
- NFX1 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OR8B12 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PID1 | c.178A>T p.K60* (on ENST00000354069 / NM_001330156.1; = p.K58* on NM_017933.5) | Nonsense Mutation (SNP) | VAF 38/182 reads (21%) | called by muse, mutect2, varscan2
- PLAGL1 | c.1018C>G p.Q340E | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLEKHG3 | c.938_944del p.K313Sfs*24 (on ENST00000394691; = p.K369Sfs*24 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 46/233 reads (20%) | called by mutect2, pindel, varscan2
- PTGS1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RGS3 | c.198G>C p.R66S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF213 | c.12826C>G p.R4276G | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2
- RPS6KC1 | c.1807A>T p.I603L | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SLC7A2 | c.1579C>A p.L527I (on ENST00000494857 / NM_001370338.1; = p.L566I on NM_003046.6) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTA1 | c.4459G>C p.A1487P | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ST7 | c.632A>T p.E211V | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- TIMELESS | c.2846A>T p.K949I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TTC24 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 67/265 reads (25%) | called by muse, mutect2, varscan2
- VHL | c.553_555delinsAA p.Y185Kfs*17 | Frame Shift Del (DEL) | VAF 60/277 reads (22%) | called by pindel, varscan2*
- WDR41 | c.514_515insG p.S172Cfs*2 | Frame Shift Ins (INS) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- ZNF318 | c.5834C>T p.S1945L | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF382 | c.882del p.K294Nfs*54 | Frame Shift Del (DEL) | VAF 46/179 reads (26%) | called by mutect2, pindel, varscan2
- ABLIM1 | c.1819T>C p.L607= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.1833C>A p.L611= | Silent (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- CDHR4 | c.1230G>A p.Q410= | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- CLMN | c.1623G>A p.K541= | Silent (SNP) | VAF 47/196 reads (24%) | catalogued as rs751186038; called by muse, mutect2, varscan2
- CYP3A5 | c.90T>C p.H30= | Silent (SNP) | VAF 57/250 reads (23%) | called by muse, mutect2, varscan2
- GATA4 | c.405C>T p.G135= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- GPR52 | c.157C>T p.L53= | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as COSV99267388; called by muse, mutect2, varscan2
- HDGFL1 | c.228C>T p.S76= | Silent (SNP) | VAF 74/285 reads (26%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.471C>T p.S157= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs527767645; called by muse, mutect2, varscan2
- KARS1 | c.1215G>C p.G405= | Silent (SNP) | VAF 87/457 reads (19%) | called by muse, mutect2, varscan2
- KCNJ4 | c.825C>T p.G275= | Silent (SNP) | VAF 42/161 reads (26%) | called by muse, mutect2, varscan2
- LRP2 | c.4557A>G p.V1519= | Silent (SNP) | VAF 110/218 reads (50%) | called by muse, mutect2, varscan2
- QPRT | c.483C>G p.R161= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2
- SHROOM2 | c.3114C>T p.G1038= | Silent (SNP) | VAF 48/76 reads (63%) | called by muse, mutect2, varscan2
- SKI | c.2085G>T p.R695= | Silent (SNP) | VAF 46/179 reads (26%) | called by muse, mutect2, varscan2
- SLC19A2 | c.75C>T p.V25= | Silent (SNP) | VAF 85/294 reads (29%) | called by muse, mutect2, varscan2
- TDRD9 | c.3129C>T p.G1043= | Silent (SNP) | VAF 63/228 reads (28%) | called by muse, mutect2, varscan2
- TTC39C | c.996C>T p.N332= (on ENST00000317571 / NM_001135993.2; = p.N271= on NM_153211.4) | Silent (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- YBX3 | c.282T>A p.T94= | Silent (SNP) | VAF 82/183 reads (45%) | called by muse, mutect2, varscan2
- AC245748.1 | c.16-26573G>A | Intron (SNP) | VAF 29/140 reads (21%) | catalogued as rs1267948731; called by muse, mutect2, varscan2
- BAIAP2 | c.54+1581C>T | Intron (SNP) | VAF 52/168 reads (31%) | catalogued as rs560242138; called by muse, mutect2, varscan2
- CFAP74 | c.296+419C>T | Intron (SNP) | VAF 43/112 reads (38%) | catalogued as rs1389634411, COSV54575351; called by muse, mutect2, varscan2
- DNAJC19 | c.*469dup | 3'UTR (INS) | VAF 84/376 reads (22%) | called by pindel, varscan2
- DUOX2 | c.513+19C>T | Intron (SNP) | VAF 13/36 reads (36%) | catalogued as rs765360507; called by muse, mutect2, varscan2
- FKBP1B | c.85+230G>A | Intron (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- GSTM2 | chr1:109668040 C>T | 5'Flank (SNP) | VAF 70/194 reads (36%) | called by muse, mutect2
- HLA-DQA1 | c.*235del | 3'UTR (DEL) | VAF 29/108 reads (27%) | called by mutect2, pindel, varscan2
- KALRN | c.7377+116C>A | Intron (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- PGRMC1 | c.*4A>G | 3'UTR (SNP) | VAF 81/129 reads (63%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.37-10237A>T | Intron (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- RXRA | n.361C>A | RNA (SNP) | VAF 24/79 reads (30%) | catalogued as rs60815492; called by muse, mutect2, varscan2
- SLC9A7P1 | n.500G>C | RNA (SNP) | VAF 135/293 reads (46%) | called by muse, mutect2, varscan2
- TANC2 | c.3676+608G>A | Intron (SNP) | VAF 34/114 reads (30%) | catalogued as rs574415946; called by muse, varscan2
- TMEM70 | c.*534G>A | 3'UTR (SNP) | VAF 21/82 reads (26%) | catalogued as rs756785098; called by muse, mutect2, varscan2
- TP53I11 | c.-148+3769G>A | Intron (SNP) | VAF 35/115 reads (30%) | catalogued as rs895915133, COSV57533958; called by muse, mutect2, varscan2
- URGCP | c.-3C>A | 5'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.426-4261_426-4260insCTGC | Intron (INS) | VAF 17/150 reads (11%) | called by muse*, mutect2
